Gene-level copy-number profile of tumor specimen TCGA-DK-A6B6-01A from TCGA case TCGA-DK-A6B6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 57.5 years (21,007 days).
Specimen TCGA-DK-A6B6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.3bb11954-24a9-425f-85e5-ab0edb161416.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A6B6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aa1506af-cf8c-47cd-af0d-f4a42d0a7196

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,848; copy number 3: 23,274; copy number 4: 22,646; copy number 5: 4,348; copy number 6: 1,260; copy number 7: 182; copy number 8: 86; copy number 9: 29; copy number 10: 81; copy number 11: 15; copy number 12: 46; copy number 14: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A6B6-01A-11D-A30D-01): tumor purity 0.52, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 444 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:100,104,919–100,996,829, 20 genes, copy number 7 (within-gene range 4–7): AC092667.1, LINC01104, LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2, PDCL3, HMGN2P22, LINC01849, AC092845.1, NANOGNBP1, LINC01868, AC092168.1, AC092168.3, NPAS2, AC092168.2, NPAS2-AS1.
- chr2:108,534,355–108,785,809, 5 genes, copy number 10 (within-gene range 3–10): LIMS1, LIMS1-AS1, AC010095.1, RPL10P5, RANBP2.
- chr2:156,011,530–156,342,348, 4 genes, copy number 12: LINC01876, HEBP2P1, AC074099.1, NR4A2.
- chr2:160,849,313–161,428,774, 14 genes, copy number 10: AC096656.1, RN7SL423P, AC009313.1, TANK-AS1, TANK, AC009299.2, LINC01806, AC009299.1, PSMD14, MXRA7P1, RNA5SP108, TBR1, AC009487.1, AC009487.2.
- chr2:161,433,874–161,625,752, 6 genes, copy number 10 (within-gene range 3–10): AC009487.3, AHCTF1P1, AC092654.1, AC062022.1, AC062022.2, KRT18P46.
- chr6:73,055,097–74,734,319, 37 genes, copy number 8 (within-gene range 4–8): PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7, AL357507.1, AL357563.1, AL356277.3, AL356277.1, AL356277.2.
- chr10:60,869,438–64,693,446, 40 genes, copy number 7–9 (within-gene range 2–9): RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35.
- chr11:68,460,731–70,436,584, 57 genes, copy number 7–12: PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 12: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr15:49,155,656–51,721,026, 58 genes, copy number 8–11 (within-gene range 3–11): GALK2, NDUFAF4P1, MIR4716, AC013452.1, RN7SL307P, FAM227B, AC022306.2, AC022306.3, AC022306.1, FGF7, DTWD1, AC025040.2, ATP8B4, AC025040.1, RNA5SP394, SLC27A2, Y_RNA, HDC, RN7SL494P, GABPB1, RNU6-94P, GABPB1-IT1, GABPB1-AS1, AC022087.1, MIR4712, AHCYP7, USP8, RNA5SP395, AC012170.1, USP50, TRPM7, AC084756.1, AC084756.2, RN7SL354P, SPPL2A, AC012100.3, AC012100.2, AC012100.1, AC021752.1, AP4E1, DCAF13P3, MIR4713HG, TNFAIP8L3, AC073964.1, CYP19A1, MIR4713, AC020891.3, MIR7973-2, MIR7973-1, AC020891.2, GLDN, AC020891.4, AC020891.1, AC066613.2, DMXL2, AC066613.1, SCG3, AC020892.1.
- chr15:53,837,271–54,633,414, 6 genes, copy number 8 (within-gene range 6–8): AC084759.1, AC084759.3, AC084759.2, UNC13C, AC010867.1, HNRNPA1P74.
- chr17:19,215,615–19,336,715, 1 gene, copy number 7 (within-gene range 3–7): EPN2.
- chr17:19,296,596–21,574,517, 125 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr17:31,709,568–32,906,584, 56 genes, copy number 10: AC007923.2, RNU6-1134P, GPR160P2, AC007923.1, AC004253.2, COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2.
- chr17:33,013,087–34,174,964, 9 genes, copy number 7–14 (within-gene range 4–14): ASIC2, AC003687.1, AC008133.2, AC008133.1, AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
